Somatic mutation profile of tumor specimen 0DIMX5 from CCDI case PBBUHC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,290 days).
Specimen 0DIMX5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4638df9-ff92-4b78-b5ea-b7f59ee67ba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1aa6fa-9ac3-4e9a-a113-0099ff7a463d

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'UTR 2, Intron 2, Splice Site 1, 3'Flank 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFIC | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59415281; called by muse, mutect2, varscan2
- EIF4A3 | c.370_372del p.K124del | In Frame Del (DEL) | VAF 322/784 reads (41%) | called by mutect2, pindel, varscan2
- LRRC18 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 93/894 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAP4K5 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 292/1259 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF8 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 309/1179 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PTTG1IP | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 214/1188 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RANBP2 | c.1063+2T>C p.X355_splice | Splice Site (SNP) | VAF 216/2413 reads (9%) | called by muse, mutect2, varscan2
- RHOU | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 131/597 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RNF128 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 411/1363 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TMEM64 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 52/596 reads (9%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); called by muse, mutect2
- ICMT | c.570G>A p.Q190= | Silent (SNP) | VAF 205/1309 reads (16%) | called by muse, mutect2, varscan2
- TRPM8 | c.1392G>A p.T464= | Silent (SNP) | VAF 216/1239 reads (17%) | catalogued as rs758752433, COSV61221107; called by muse, mutect2, varscan2
- ADCY4 | c.1569-45G>T | Intron (SNP) | VAF 71/280 reads (25%) | called by muse, mutect2, varscan2
- ATG9B | chr7:151013191 C>T | 3'Flank (SNP) | VAF 57/199 reads (29%) | catalogued as rs1255687315, COSV52492542; called by muse, mutect2, varscan2
- COMMD9 | c.353-17A>G | Intron (SNP) | VAF 186/756 reads (25%) | called by muse, mutect2, varscan2
- CTBS | c.*1838A>G | 3'UTR (SNP) | VAF 182/620 reads (29%) | called by muse, mutect2, varscan2
- DPPA3 | c.-60C>T | 5'UTR (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- MYB | c.*25T>G | 3'UTR (SNP) | VAF 115/765 reads (15%) | called by muse, mutect2, varscan2
